Somatic mutation profile of tumor specimen C3N-03876-01 (aliquot CPT0237480007) from CPTAC case C3N-03876, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 65.3 years (23,849 days).
Specimen C3N-03876-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8182dcfc-ad61-4e59-90e4-058f17589a27.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03876-31 (Blood Derived Normal), aliquot CPT0237540002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e65853a9-332c-4ab9-a46c-cac1e77f7097

The open-access MAF lists 178 somatic variants for this specimen: 111 protein-altering or splice-affecting, 43 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, Silent 43, Intron 10, Nonsense Mutation 5, Splice Site 5, Frame Shift Ins 4, RNA 4, 5'UTR 4, 3'UTR 3, Frame Shift Del 3, 3'Flank 3, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.16294C>T p.R5432W | Missense Mutation (SNP) | VAF 87/242 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1565753611, CM126448, COSV56411084; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 243/999 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.581T>G p.L194R | Missense Mutation (SNP) | VAF 274/670 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519998, COSV52663681, COSV52677924, COSV52679257, COSV52713187; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ACP3 | c.880A>T p.S294C | Missense Mutation (SNP) | VAF 30/506 reads (6%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.953); catalogued as COSV104413339, COSV60484790; called by muse, mutect2
- AGAP2 | c.1145G>A p.G382D | Missense Mutation (SNP) | VAF 88/136 reads (65%) | SIFT tolerated (0.09); PolyPhen benign (0.104); catalogued as rs746865207; called by muse, mutect2, varscan2
- AMER2 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 132/422 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.062); catalogued as COSV100766157; called by muse, mutect2, varscan2
- BCL11B | c.1130C>T p.P377L (on ENST00000357195 / NM_001282237.2; = p.P306L on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/103 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as rs1273945817; called by muse, mutect2
- BRD7 | c.1922C>T p.T641M | Missense Mutation (SNP) | VAF 30/314 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs768989702, COSV54268858; called by muse, mutect2
- BRF1 | c.748A>T p.I250F | Missense Mutation (SNP) | VAF 61/373 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100527349; called by muse, mutect2, varscan2
- C1QL1 | c.698A>G p.K233R | Missense Mutation (SNP) | VAF 118/635 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.963); catalogued as rs987431187; called by muse, mutect2, varscan2
- CABP1 | c.983G>T p.R328L (on ENST00000316803 / NM_001033677.1; = p.R125L on NM_004276.5) | Missense Mutation (SNP) | VAF 96/340 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV56457899, COSV56459072; called by muse, mutect2, varscan2
- CNTN5 | c.194C>A p.S65Y | Missense Mutation (SNP) | VAF 62/906 reads (7%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.276); catalogued as rs200519976, COSV54359337; called by muse, mutect2
- CNTNAP5 | c.1493C>T p.T498I | Missense Mutation (SNP) | VAF 47/142 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV70481398; called by muse, mutect2, varscan2
- DST | c.18295A>G p.I6099V (on ENST00000361203 / NM_001374722.1; = p.I3796V on NM_015548.5) | Missense Mutation (SNP) | VAF 71/134 reads (53%) | SIFT tolerated (0.61); PolyPhen benign (0.219); catalogued as COSV55017591; called by muse, mutect2, varscan2
- ENPP3 | c.2519G>A p.R840H | Missense Mutation (SNP) | VAF 176/578 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs201810317, COSV62952960; called by muse, mutect2, varscan2
- FCRL2 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 172/540 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.119); catalogued as rs144215277, COSV100829811; called by muse, mutect2, varscan2
- FOXP1 | c.211C>T p.Q71* | Nonsense Mutation (SNP) | VAF 13/264 reads (5%) | catalogued as COSV59558059; called by muse, mutect2
- FSD2 | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201802510; called by muse, mutect2, varscan2
- HSPBAP1 | c.974T>G p.L325* | Nonsense Mutation (SNP) | VAF 145/225 reads (64%) | catalogued as rs537005109; called by muse, mutect2, varscan2
- MCIDAS | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 52/353 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.03); catalogued as rs1463644495; called by muse, mutect2
- MFNG | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 155/487 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs150961532; called by muse, mutect2, varscan2
- MYB | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 153/488 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.76); catalogued as COSV57198792; called by muse, mutect2, varscan2
- MYEF2 | c.20C>G p.A7G | Missense Mutation (SNP) | VAF 63/305 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.046); catalogued as COSV51054736; called by muse, mutect2, varscan2
- OGDHL | c.373C>T p.Q125* | Nonsense Mutation (SNP) | VAF 45/124 reads (36%) | catalogued as rs932093782; called by muse, mutect2, varscan2
- OR10Z1 | c.807G>C p.E269D | Missense Mutation (SNP) | VAF 164/509 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV63526261; called by muse, mutect2, varscan2
- OSTC | c.157A>G p.I53V | Missense Mutation (SNP) | VAF 83/307 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as rs1343852089; called by muse, mutect2, varscan2
- PAX9 | c.631G>C p.V211L | Missense Mutation (SNP) | VAF 580/744 reads (78%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV64062071; called by muse, mutect2, varscan2
- PCDHA8 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 102/346 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs782259152, COSV65335857; called by muse, mutect2, varscan2
- PCDHB13 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 137/691 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.93); catalogued as rs782198068, COSV53396237; called by muse, varscan2
- PDZRN4 | c.524_544del p.L175_L181del | In Frame Del (DEL) | VAF 100/384 reads (26%) | catalogued as rs745973484; called by mutect2, varscan2
- PNPLA7 | c.2672G>A p.R891K | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.076); catalogued as COSV52998043; called by muse, mutect2, varscan2
- PRKCI | c.1753A>G p.I585V | Missense Mutation (SNP) | VAF 74/221 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0.009); catalogued as rs374370739; called by muse, mutect2, varscan2
- RGPD3 | c.2419G>A p.D807N | Missense Mutation (SNP) | VAF 126/499 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as COSV58737560; called by muse, varscan2
- RP1 | c.2297G>A p.R766Q | Missense Mutation (SNP) | VAF 157/289 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs901019289; called by muse, mutect2, varscan2
- SCN7A | c.3632C>T p.T1211M | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs907331268; called by muse, mutect2
- SGSH | c.423G>C p.E141D | Missense Mutation (SNP) | VAF 156/542 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.58); catalogued as rs769601150; called by muse, mutect2, varscan2
- SYCE1L | c.17A>T p.K6I | Missense Mutation (SNP) | VAF 49/316 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as rs899053487; called by muse, mutect2, varscan2
- TDRD6 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 167/645 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs1402781192; called by muse, mutect2, varscan2
- TTYH2 | c.335G>A p.S112N | Missense Mutation (SNP) | VAF 37/388 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs781470973, COSV53910373; called by muse, mutect2
- UBXN4 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs772270264; called by muse, mutect2, varscan2
- ZDHHC4 | c.373A>G p.I125V | Missense Mutation (SNP) | VAF 73/204 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as rs375508426; called by muse, mutect2, varscan2
- ZNF341 | c.1898G>A p.R633H (on ENST00000375200 / NM_001282935.1; = p.R626H on NM_032819.4) | Missense Mutation (SNP) | VAF 51/482 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780468263, COSV61008904; called by muse, mutect2, varscan2
- ADAM29 | c.1789G>C p.E597Q | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- ADGRG6 | c.1651A>G p.K551E | Missense Mutation (SNP) | VAF 105/396 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- AJUBA | c.1170_1171dup p.Y391Ffs*20 | Frame Shift Ins (INS) | VAF 61/119 reads (51%) | called by mutect2, pindel, varscan2
- ALG8 | c.170A>C p.Y57S | Missense Mutation (SNP) | VAF 33/226 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- AMPD3 | c.421G>T p.A141S (on ENST00000396553 / NM_001025389.2; = p.A150S on NM_000480.3) | Missense Mutation (SNP) | VAF 248/1012 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.007); called by mutect2, varscan2
- ANKRD11 | c.3520G>T p.E1174* | Nonsense Mutation (SNP) | VAF 119/1204 reads (10%) | called by muse, mutect2, varscan2
- ATP10A | c.486A>T p.E162D | Missense Mutation (SNP) | VAF 73/376 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- BBS7 | c.2015-2A>G p.X672_splice | Splice Site (SNP) | VAF 10/120 reads (8%) | called by muse, mutect2
- C8A | c.1112A>G p.D371G | Missense Mutation (SNP) | VAF 147/648 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- CAPN3 | c.1075C>G p.P359A | Missense Mutation (SNP) | VAF 218/543 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC120 | c.1454T>C p.L485P | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD96 | c.929T>C p.L310P (on ENST00000283285 / NM_198196.3; = p.L294P on NM_005816.5) | Missense Mutation (SNP) | VAF 48/301 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CIC | c.218-2A>T p.X73_splice | Splice Site (SNP) | VAF 17/367 reads (5%) | called by muse, mutect2
- COL22A1 | c.2578C>T p.H860Y | Missense Mutation (SNP) | VAF 87/381 reads (23%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- CPLANE1 | c.8338G>T p.D2780Y | Missense Mutation (SNP) | VAF 72/163 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- CXCR2 | c.665T>G p.V222G | Missense Mutation (SNP) | VAF 81/273 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- DNAH5 | c.13347G>T p.W4449C | Missense Mutation (SNP) | VAF 106/418 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DPH6 | c.428A>G p.Q143R | Missense Mutation (SNP) | VAF 27/178 reads (15%) | SIFT tolerated (0.73); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- DPP10 | c.1868_1875del p.E623Gfs*16 | Frame Shift Del (DEL) | VAF 7/42 reads (17%) | called by mutect2, pindel, varscan2
- DSC3 | c.1975G>T p.A659S | Missense Mutation (SNP) | VAF 85/332 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- EFCAB6 | c.1530dup p.N511* | Frame Shift Ins (INS) | VAF 89/357 reads (25%) | called by mutect2, pindel, varscan2
- FAM135A | c.2710G>A p.D904N (on ENST00000370479 / NM_001351599.1; = p.D691N on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- FAM135B | c.947C>T p.T316I | Missense Mutation (SNP) | VAF 22/602 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- FAM184A | c.3247C>G p.P1083A | Missense Mutation (SNP) | VAF 93/536 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FRY | c.2700G>C p.K900N | Missense Mutation (SNP) | VAF 98/796 reads (12%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- GPR34 | c.830T>C p.I277T | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- GREB1L | c.2200G>T p.G734C | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HECW1 | c.4063C>G p.Q1355E | Missense Mutation (SNP) | VAF 125/482 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- HIVEP1 | c.4904dup p.M1635Ifs*9 | Frame Shift Ins (INS) | VAF 87/321 reads (27%) | called by mutect2, pindel, varscan2
- HSF2 | c.1441A>G p.I481V | Missense Mutation (SNP) | VAF 162/342 reads (47%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- INSYN2B | c.624_627del p.Y209Tfs*20 | Frame Shift Del (DEL) | VAF 18/120 reads (15%) | called by mutect2, pindel, varscan2
- KALRN | c.7449G>T p.L2483F (on ENST00000360013 / NM_001024660.4; = p.L786F on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/430 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- KMT2D | c.15157_15158del p.D5053Pfs*18 | Frame Shift Del (DEL) | VAF 38/205 reads (19%) | called by mutect2, pindel, varscan2
- LANCL2 | c.460C>A p.P154T | Missense Mutation (SNP) | VAF 214/786 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MACROH2A2 | c.197A>G p.N66S | Missense Mutation (SNP) | VAF 94/347 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAP2 | c.1652G>C p.G551A | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- MLH3 | c.1084A>G p.I362V | Missense Mutation (SNP) | VAF 62/91 reads (68%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- MON2 | c.4245A>T p.E1415D | Missense Mutation (SNP) | VAF 64/245 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MTM1 | c.136+8C>T | Splice Region (SNP) | VAF 101/170 reads (59%) | called by muse, mutect2, varscan2
- MTMR4 | c.3452A>T p.K1151M | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC19 | c.658G>T p.E220* | Nonsense Mutation (SNP) | VAF 27/183 reads (15%) | called by muse, mutect2, varscan2
- NHLRC2 | c.2011G>A p.D671N | Missense Mutation (SNP) | VAF 134/316 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- OTOF | c.5539A>G p.I1847V (on ENST00000272371 / NM_194248.3; = p.I1080V on NM_004802.4) | Missense Mutation (SNP) | VAF 143/486 reads (29%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- PACS1 | c.2560C>T p.R854C | Missense Mutation (SNP) | VAF 25/701 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- PCYOX1 | c.1386_1389dup p.A464Cfs*31 | Frame Shift Ins (INS) | VAF 99/320 reads (31%) | called by mutect2, pindel, varscan2
- PITPNB | c.425A>G p.D142G | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PLD5 | c.1131A>T p.R377S (on ENST00000442594; = p.R315S on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- PMM1 | c.511A>G p.K171E | Missense Mutation (SNP) | VAF 14/380 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.11); called by muse, mutect2
- PREX2 | c.688C>G p.H230D | Missense Mutation (SNP) | VAF 28/247 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- PRSS56 | c.538C>A p.H180N | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- RSBN1L | c.2078A>G p.Y693C | Missense Mutation (SNP) | VAF 141/320 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RSC1A1 | c.394A>T p.S132C | Missense Mutation (SNP) | VAF 58/325 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- RTL1 | c.3431A>T p.Q1144L | Missense Mutation (SNP) | VAF 60/706 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); called by muse, mutect2
- SETBP1 | c.540+3A>C | Splice Region (SNP) | VAF 108/452 reads (24%) | called by muse, mutect2, varscan2
- SPEG | c.542C>T p.S181L | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- SYNJ1 | c.1066-2A>G p.X356_splice | Splice Site (SNP) | VAF 13/150 reads (9%) | called by muse, mutect2
- TAF7L | c.168G>T p.Q56H | Missense Mutation (SNP) | VAF 236/396 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TATDN3 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 13/249 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2
- TCTN1 | c.1274A>T p.E425V (on ENST00000551590 / NM_001173975.3; = p.E411V on NM_024549.6) | Missense Mutation (SNP) | VAF 48/505 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.644); called by muse, mutect2
- TKTL1 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 54/86 reads (63%) | SIFT tolerated (0.13); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- TMEM120A | c.785-1G>A p.X262_splice | Splice Site (SNP) | VAF 213/479 reads (44%) | called by muse, mutect2, varscan2
- TRPM6 | c.297T>G p.N99K | Missense Mutation (SNP) | VAF 215/639 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- TUFT1 | c.1016A>T p.E339V | Missense Mutation (SNP) | VAF 27/277 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- UQCC1 | c.338T>C p.I113T | Missense Mutation (SNP) | VAF 7/182 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.428); called by muse, mutect2
- USP28 | c.244G>T p.A82S | Missense Mutation (SNP) | VAF 17/302 reads (6%) | SIFT tolerated (0.94); PolyPhen benign (0.011); called by muse, mutect2
- VWA8 | c.373-2A>G p.X125_splice | Splice Site (SNP) | VAF 121/235 reads (51%) | called by muse, mutect2, varscan2
- ZEB1 | c.1942G>A p.E648K | Missense Mutation (SNP) | VAF 205/722 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF181 | c.1345A>C p.N449H | Missense Mutation (SNP) | VAF 46/182 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- ZNF763 | c.85T>C p.Y29H (on ENST00000358987 / NM_001367172.2; = p.Y32H on NM_001012753.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 137/486 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- ADAT1 | c.378A>G p.K126= | Silent (SNP) | VAF 36/126 reads (29%) | called by muse, mutect2, varscan2
- ASXL1 | c.753T>C p.D251= | Silent (SNP) | VAF 117/530 reads (22%) | called by muse, mutect2, varscan2
- BTNL2 | c.786T>C p.D262= | Silent (SNP) | VAF 50/195 reads (26%) | called by muse, mutect2
- CARMIL1 | c.3903G>C p.L1301= | Silent (SNP) | VAF 52/286 reads (18%) | catalogued as COSV61522783; called by muse, mutect2, varscan2
- CASP12 | c.585C>T p.I195= | Silent (SNP) | VAF 58/513 reads (11%) | called by muse, mutect2, varscan2
- CAVIN2 | c.987A>G p.E329= | Silent (SNP) | VAF 159/485 reads (33%) | catalogued as rs1177825690; called by muse, mutect2, varscan2
- DNAH9 | c.7960C>T p.L2654= | Silent (SNP) | VAF 267/797 reads (34%) | called by muse, mutect2, varscan2
- DPP10 | c.1377A>T p.G459= | Silent (SNP) | VAF 45/122 reads (37%) | called by muse, mutect2, varscan2
- DSCAM | c.2319C>T p.G773= | Silent (SNP) | VAF 40/90 reads (44%) | catalogued as rs757360658, COSV68027565; called by muse, mutect2, varscan2
- EML5 | c.3207G>A p.A1069= | Silent (SNP) | VAF 30/416 reads (7%) | catalogued as rs561391485; called by muse, mutect2
- EXOC8 | c.1068G>T p.A356= | Silent (SNP) | VAF 80/262 reads (31%) | catalogued as rs374382054; called by muse, mutect2, varscan2
- EYA1 | c.1731C>T p.H577= | Silent (SNP) | VAF 31/984 reads (3%) | catalogued as rs995839854; called by muse, mutect2
- FAH | c.891C>T p.I297= | Silent (SNP) | VAF 82/491 reads (17%) | catalogued as rs1037374579, COSV55720424; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAM13C | c.183C>T p.P61= | Silent (SNP) | VAF 124/675 reads (18%) | called by muse, mutect2, varscan2
- FLG | c.9093G>A p.V3031= | Silent (SNP) | VAF 104/878 reads (12%) | called by muse, mutect2, varscan2
- GABBR1 | c.1017C>T p.F339= | Silent (SNP) | VAF 77/307 reads (25%) | catalogued as COSV100589729, COSV63543036; called by muse, mutect2, varscan2
- GLI1 | c.1138C>A p.R380= | Silent (SNP) | VAF 372/517 reads (72%) | catalogued as COSV57358068; called by muse, mutect2, varscan2
- H3-4 | c.264G>A p.S88= | Silent (SNP) | VAF 212/859 reads (25%) | catalogued as COSV64210626; called by muse, mutect2, varscan2
- HAO1 | c.960C>A p.G320= | Silent (SNP) | VAF 20/256 reads (8%) | catalogued as COSV101113240; called by muse, mutect2
- IGLV3-22 | c.258G>T p.G86= | Silent (SNP) | VAF 157/391 reads (40%) | called by muse, mutect2, varscan2
- KIAA0319L | c.2976A>G p.K992= | Silent (SNP) | VAF 40/152 reads (26%) | called by muse, mutect2
- L3MBTL3 | c.2121A>G p.K707= | Silent (SNP) | VAF 105/321 reads (33%) | called by muse, mutect2, varscan2
- LAMA1 | c.3045C>T p.V1015= | Silent (SNP) | VAF 70/814 reads (9%) | called by muse, mutect2
- LCA5L | c.1971G>A p.K657= | Silent (SNP) | VAF 44/128 reads (34%) | called by muse, mutect2
- LRRK2 | c.3795C>G p.G1265= | Silent (SNP) | VAF 102/378 reads (27%) | called by muse, mutect2, varscan2
- LY6D | c.264G>A p.Q88= | Silent (SNP) | VAF 80/564 reads (14%) | called by muse, mutect2, varscan2
- MUC4 | c.1314C>T p.L438= | Silent (SNP) | VAF 75/412 reads (18%) | catalogued as COSV100638826; called by muse, mutect2, varscan2
- MYO3B | c.3624A>C p.G1208= | Silent (SNP) | VAF 18/184 reads (10%) | called by muse, mutect2
- NLRC5 | c.4050C>G p.S1350= | Silent (SNP) | VAF 18/570 reads (3%) | called by muse, mutect2
- OAS3 | c.2709C>T p.S903= | Silent (SNP) | VAF 172/256 reads (67%) | catalogued as COSV99966417; called by muse, mutect2, varscan2
- OR11H1 | c.738G>A p.G246= | Silent (SNP) | VAF 161/784 reads (21%) | called by muse, varscan2
- OR52E8 | c.441C>T p.I147= | Silent (SNP) | VAF 78/166 reads (47%) | called by muse, mutect2, varscan2
- PIF1 | c.501G>A p.P167= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as rs201870033; called by muse, mutect2
- PNLIPRP2 | c.882C>A p.L294= | Silent (SNP) | VAF 43/343 reads (13%) | called by muse, mutect2, varscan2
- POLH | c.1644A>C p.S548= | Silent (SNP) | VAF 68/666 reads (10%) | called by muse, mutect2, varscan2
- RABGEF1 | c.321G>A p.K107= (on ENST00000439720 / NM_001287061.2; = p.K94= on NM_014504.3 and 29 other RefSeq transcripts) | Silent (SNP) | VAF 18/387 reads (5%) | catalogued as rs1441456284; called by muse, mutect2
- SERPINI2 | c.1114C>T p.L372= | Silent (SNP) | VAF 9/235 reads (4%) | catalogued as COSV52989227; called by muse, mutect2
- SNTB2 | c.675T>C p.F225= | Silent (SNP) | VAF 45/876 reads (5%) | called by muse, mutect2
- TUBA3C | c.198G>A p.V66= | Silent (SNP) | VAF 14/260 reads (5%) | called by muse, mutect2
- TUBB3 | c.48C>T p.I16= | Silent (SNP) | VAF 189/606 reads (31%) | called by muse, mutect2, varscan2
- VWA5A | c.1320C>A p.T440= | Silent (SNP) | VAF 24/100 reads (24%) | called by muse, mutect2, varscan2
- XIRP2 | c.7515A>G p.Q2505= (on ENST00000628543; = p.Q2680= on NM_152381.6) | Silent (SNP) | VAF 130/329 reads (40%) | called by muse, mutect2, varscan2
- ZNF808 | c.1329G>A p.E443= | Silent (SNP) | VAF 41/314 reads (13%) | catalogued as rs943830300; called by muse, mutect2, varscan2
- AC092118.1 | n.855G>T | RNA (SNP) | VAF 203/540 reads (38%) | catalogued as rs781998699; called by muse, mutect2, varscan2
- ACSM1 | c.1197+222G>A | Intron (SNP) | VAF 120/397 reads (30%) | called by muse, mutect2, varscan2
- AL109984.1 | chr20:52097056 T>A | 3'Flank (SNP) | VAF 36/187 reads (19%) | called by muse, mutect2, varscan2
- ANKRD20A5P | n.52A>G | RNA (SNP) | VAF 178/589 reads (30%) | called by muse, mutect2, varscan2
- ATP6V0B | c.591+88C>T | Intron (SNP) | VAF 30/324 reads (9%) | called by muse, mutect2
- CCNC | c.798-602G>C | Intron (SNP) | VAF 47/262 reads (18%) | called by muse, mutect2, varscan2
- COL4A5 | c.4803+11C>G | Intron (SNP) | VAF 72/212 reads (34%) | called by muse, mutect2, varscan2
- CYP2S1 | c.-8C>T | 5'UTR (SNP) | VAF 149/389 reads (38%) | called by muse, mutect2, varscan2
- DIS3L2 | c.*12C>T | 3'UTR (SNP) | VAF 180/538 reads (33%) | catalogued as rs749084554; called by muse, mutect2, varscan2
- ENTPD1 | c.1074+16G>A | Intron (SNP) | VAF 233/349 reads (67%) | called by muse, mutect2, varscan2
- GVINP1 | n.2780G>A | RNA (SNP) | VAF 65/152 reads (43%) | called by muse, mutect2, varscan2
- IFNLR1 | c.510+87T>G | Intron (SNP) | VAF 49/116 reads (42%) | called by muse, mutect2, varscan2
- LPCAT3 | c.461-10C>T | Intron (SNP) | VAF 126/519 reads (24%) | called by muse, mutect2, varscan2
- MEG3 | chr14:100860759 C>T | 3'Flank (SNP) | VAF 202/283 reads (71%) | catalogued as rs955047966; called by muse, mutect2, varscan2
- MIR6511A3 | chr16:16372470 C>T | 3'Flank (SNP) | VAF 53/300 reads (18%) | called by mutect2, varscan2
- MPRIP | c.2163+4748C>G | Intron (SNP) | VAF 11/142 reads (8%) | called by muse, mutect2
- NXPH3 | c.*2528C>T | 3'UTR (SNP) | VAF 23/131 reads (18%) | called by muse, mutect2, varscan2
- POU4F1 | c.-12C>G | 5'UTR (SNP) | VAF 42/558 reads (8%) | called by muse, mutect2
- RHOC | c.*34T>C | 3'UTR (SNP) | VAF 127/514 reads (25%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.89-62C>T | Intron (SNP) | VAF 24/195 reads (12%) | catalogued as COSV56152779; called by muse, mutect2, varscan2
- TCP10L3 | n.2631C>G | RNA (SNP) | VAF 144/840 reads (17%) | called by muse, varscan2
- TULP4 | c.1486+16G>A | Intron (SNP) | VAF 216/527 reads (41%) | catalogued as rs371734335; called by muse, mutect2, varscan2
- ZNF169 | c.-11A>T | 5'UTR (SNP) | VAF 32/266 reads (12%) | called by muse, mutect2, varscan2
- ZNF766 | c.-5G>C | 5'UTR (SNP) | VAF 60/371 reads (16%) | called by muse, mutect2, varscan2
